Gene-level copy-number profile of specimen HCM-CSHL-0434-C24-85M from HCMI case HCM-CSHL-0434-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,282 days).
Specimen HCM-CSHL-0434-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed487465-5089-412f-b5d5-33ba821aa7af.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0434-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/5cd64c16-8077-400c-ab80-684f41bdc09e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 435; copy number 1: 13,840; copy number 2: 39,315; copy number 3: 4,348; copy number 4: 798; copy number 5: 43; copy number 6: 69; copy number 7: 14; copy number 11: 14; copy number 12: 1; copy number 13: 34; copy number 14: 5.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,439,346–64,498,745, 7 genes: SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 180 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:32,934,396–33,804,176, 3 genes, copy number 5: NPAS3, AL161851.1, AL161851.2.
- chr19:29,489,775–29,824,312, 7 genes, copy number 7 (within-gene range 3–7): AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1.
- chr19:33,067,175–33,067,433, 1 gene, copy number 6: AC008521.2.
- chr19:34,837,889–35,717,038, 64 genes, copy number 5–6 (broad region; genes not listed).
- chr19:39,083,913–40,898,282, 105 genes, copy number 5–14 (within-gene range 2–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,412. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
